Gene-level copy-number profile of tumor specimen TCGA-3B-A9HO-01A from TCGA case TCGA-3B-A9HO, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 75.7 years (27,664 days).
Specimen TCGA-3B-A9HO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.6af033f7-10e9-4692-b0bf-4c54e6e23e88.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3B-A9HO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/76789c36-fc65-4352-b7a4-295178aa581a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 256; copy number 1: 7,399; copy number 2: 47,777; copy number 3: 3,152; copy number 4: 302; copy number 5: 136; copy number 6: 111; copy number 7: 103; copy number 8: 89; copy number 9: 19; copy number 10: 60; copy number 11: 73; copy number 12: 2; copy number 15: 149; copy number 16: 1; copy number 18: 13; copy number 19: 1; copy number 20: 11; copy number 21: 1; copy number 22: 15; copy number 23: 22; copy number 24: 4; copy number 25: 4; copy number 27: 4; copy number 28: 1; copy number 29: 2; copy number 30: 1; copy number 31: 2; copy number 33: 2; copy number 34: 10; copy number 35: 1; copy number 37: 30; copy number 39: 13; copy number 41: 9; copy number 43: 4; copy number 44: 1; copy number 45: 24; copy number 53: 2; copy number 60: 5; copy number 67: 4; copy number 103: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3B-A9HO-01A-11D-A386-01): tumor purity 0.31, ploidy 3.73, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 104 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:207,321,532–207,969,329, 18 genes: CD55, AL391597.1, CR2, CR1, AL137789.1, CR1L, CD46P1, CDCA4P3, RNA5SP534, AL137789.2, CD46, CDCA4P4, MIR29B2CHG, MIR29C, MIR29B2, CD34, AL356275.1, LINC02767.
- chr18:76,357,682–80,247,514, 86 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 930 genes in 92 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:154,502,219–154,628,013, 7 genes, copy number 7 (within-gene range 4–7): TDRD10, UBE2Q1, UBE2Q1-AS1, AL592078.2, CHRNB2, AL592078.1, ADAR.
- chr1:161,433,444–162,599,842, 40 genes, copy number 5 (within-gene range 1–5): AL831711.1, FCGR2A, AL590385.2, HSPA6, RPS23P10, FCGR3A, AL590385.1, FCGR2C, HSPA7, RPS23P9, FCGR3B, FCGR2B, AL451067.1, RPL31P11, Y_RNA, FCRLA, FCRLB, RN7SL466P, DUSP12, AL359541.1, ATF6, AL391825.1, OLFML2B, AL590408.1, NOS1AP, AL450163.1, MIR4654, AL512785.1, RNA5SP61, MIR556, AL512785.2, SPATA46, C1orf226, SH2D1B, SLAMF6P1, UHMK1, UQCRBP2, AL596325.1, UAP1, AL596325.2.
- chr1:173,714,941–173,858,808, 6 genes, copy number 18 (within-gene range 1–18): KLHL20, BX248409.1, RN7SKP160, CENPL, Y_RNA, DARS2.
- chr5:1,201,595–1,523,962, 12 genes, copy number 10 (within-gene range 2–10): SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1.
- chr5:1,850,950–2,262,023, 12 genes, copy number 11: AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA, AC092266.1.
- chr5:7,830,378–8,366,437, 10 genes, copy number 5 (within-gene range 1–5): C5orf49, MTRR, FASTKD3, AC025174.1, RNU1-76P, AC116361.1, AC091941.1, AC091912.2, AC091912.1, AC091912.3.
- chr5:9,363,275–10,777,062, 52 genes, copy number 11: AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221, AC091905.2, AC091905.3, AC091905.1, AC091905.4, AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1.
- chr5:15,384,220–15,939,795, 5 genes, copy number 6 (within-gene range 1–6): MARK2P5, AC114964.2, AC114964.1, FBXL7, CTD-2350J17.1.
- chr8:66,480,648–68,852,763, 38 genes, copy number 8–22: AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1.
- chr8:94,879,770–95,116,455, 13 genes, copy number 15: CCNE2, AC087752.4, AC087752.1, NDUFAF6, TP53INP1, AC087752.3, AC087752.2, AC068189.2, RNU6-1209P, MIR3150BHG, AC068189.1, MIR3150B, MIR3150A.
- chr8:95,986,108–96,611,790, 13 genes, copy number 39: AC012339.1, GAPDHP30, AC007992.1, AP003465.2, GDF6, UQCRB, AP003465.1, MTERF3, PTDSS1, Y_RNA, AP003548.1, RNU6-1172P, SDC2.
- chr12:47,728,151–47,833,132, 8 genes, copy number 10 (within-gene range 2–10): AC004241.5, AC004241.2, RAPGEF3, SLC48A1, AC004241.4, HDAC7, AC004466.1, AC004466.3.
- chr12:48,183,644–48,500,961, 20 genes, copy number 23: CCDC184, AC074029.4, AC024257.3, OR10AD1, AC024257.1, AC024257.5, H1-7, AC024257.2, ZNF641, AC090115.1, OR5BK1P, AC024257.4, OR5BT1P, OR5BJ1P, OR8S21P, OR8T1P, ANP32D, C12orf54, AC089987.2, RPS10P20.
- chr12:55,193,882–55,263,431, 4 genes, copy number 67: OR10U1P, OR10A7, OR6C74, OR6C69P.
- chr12:57,674,665–57,984,761, 28 genes, copy number 37: RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:62,139,999–62,417,431, 6 genes, copy number 9–44: AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP.
- chr12:67,440,998–67,753,817, 7 genes, copy number 8: LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1.
- chr12:68,272,443–68,451,663, 4 genes, copy number 22 (within-gene range 3–22): MDM1, LINC02384, AC022511.1, AC008033.3.
- chr12:68,686,951–69,959,097, 34 genes, copy number 8–45 (within-gene range 2–45): NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL.
- chr12:76,025,447–76,116,100, 6 genes, copy number 9: PHLDA1, AC011611.3, AC011611.4, NAP1L1, AC011611.5, AC233290.2.
- chr12:80,763,151–80,937,925, 4 genes, copy number 27 (within-gene range 2–27): LINC01490, LIN7A, MIR617, AC078886.1.
- chr12:88,033,846–88,142,099, 4 genes, copy number 43: C12orf29, CEP290, RNA5SP364, AC091516.1.
- chr12:93,945,041–94,307,675, 5 genes, copy number 15 (within-gene range 2–41): AC012464.3, RN7SKP263, AC123567.1, PLXNC1, AC123567.2.
- chr12:110,491,083–110,746,206, 9 genes, copy number 15 (within-gene range 2–15): VPS29, AC002350.2, RAD9B, PPTC7, TCTN1, RN7SL387P, HVCN1, PPP1CC, AC144522.1.
- chr12:115,755,262–115,886,137, 4 genes, copy number 5 (within-gene range 3–5): AC009387.1, LINC02463, AC012157.1, AC012157.3.
- chr12:129,521,303–129,854,944, 6 genes, copy number 18: AC130404.1, AC130404.2, AC117373.1, AC117373.2, AC055717.3, AC055717.1.
- chr19:39,631,300–39,981,764, 19 genes, copy number 8: AC005176.2, AC005176.1, RPS29P30, LGALS16, LGALS17A, AC005515.1, AC093063.1, RPS29P27, LGALS14, AC006133.1, CLC, LEUTX, AC005393.1, DYRK1B, MIR6719, FBL, FCGBP, PRR13P5, PSMC4.
- chr19:41,169,861–41,586,844, 30 genes, copy number 7–20: RPL36P16, RN7SL718P, CYP2S1, AXL, AC011510.1, HNRNPUL1, RN7SL34P, TGFB1, AC011462.5, CCDC97, AC011462.1, TMEM91, B9D2, AC011462.4, EXOSC5, BCKDHA, AC011462.3, AC011462.2, B3GNT8, DMAC2, Metazoa_SRP, ERICH4, PCAT19, AC243960.2, PLEKHA3P1, AC243960.3, LINC01480, AC243960.1, CEACAM21, AC243960.10.
- chr19:41,673,303–41,997,497, 18 genes, copy number 8–24: CEACAM7, CEACAM5, AC243967.1, CEACAM6, AC243967.2, CEACAM3, HNRNPA1P52, AC243967.3, LYPD4, DMRTC2, RPS19, MIR6797, CD79A, ARHGEF1, ERFL, RABAC1, AC010616.1, ATP1A3.
- chr20:22,668,480–23,086,324, 11 genes, copy number 7: LINC01747, AL158175.1, KRT18P3, CYB5AP4, AL353132.1, AL049651.1, AL049651.2, SSTR4, THBD, AL118508.3, CD93.
- chr21:26,835,755–28,023,233, 14 genes, copy number 6: ADAMTS1, AP001599.1, ADAMTS5, MIR4759, GPX1P2, AP001605.1, AP001604.1, EIF4A1P1, RPL10P1, NCSTNP1, LINC01673, LINC00113, AJ006995.1, LINC00314.
- chr21:28,328,738–28,992,956, 7 genes, copy number 6 (within-gene range 2–6): AF165147.1, LINC00161, U6, N6AMT1, HSPD1P7, THUMPD1P1, LTN1.
- chr21:30,089,717–30,375,378, 13 genes, copy number 6–7: AF096876.1, CLDN17, LINC00307, CLDN8, RPL8P2, KRTAP24-1, KRTAP25-1, KRTAP26-1, KRTAP27-1, KRTAP23-1, KRTAP13-6P, KRTAP13-2, MIR4327.
- chr21:31,038,159–34,426,017, 88 genes, copy number 5–10 (within-gene range 2–12) (broad region; genes not listed).
- chr21:38,380,027–39,929,397, 43 genes, copy number 5–7 (within-gene range 3–7): ERG, SNRPGP13, AP001037.1, LINC00114, ETS2, AP001042.1, AP001042.2, AP001042.3, AP001043.1, SNORA62, RPSAP64, LINC01700, AF064858.1, AF064858.3, AF064858.2, RPL23AP12, PCBP2P1, AF129408.2, PSMG1, BRWD1, AF129408.1, TIMM9P2, BRWD1-IT1, METTL21AP1, BRWD1-AS2, BRWD1-AS1, HMGN1, Y_RNA, RNF6P1, GET1, GET1-SH3BGR, LCA5L, SH3BGR, MIR6508, MYL6P2, RPS26P4, JCADP1, B3GALT5, B3GALT5-AS1, AF064860.1, AF064860.2, IGSF5, PCP4.
- chr21:42,009,194–42,350,997, 7 genes, copy number 8: ZNF295-AS1, UMODL1, UMODL1-AS1, ABCG1, RNA5SP492, TFF3, TFF2.
- chr21:43,140,523–46,665,124, 152 genes, copy number 6–15 (broad region; genes not listed).
- chr22:26,169,462–26,423,193, 4 genes, copy number 9 (within-gene range 3–9): SEZ6L, SEZ6L-AS1, RNA5SP495, Z99714.1.
- chr22:38,921,227–39,279,897, 18 genes, copy number 7 (within-gene range 3–7): AL022318.1, APOBEC3A, APOBEC3B, APOBEC3B-AS1, APOBEC3C, AL022318.4, APOBEC3D, APOBEC3F, AL022318.2, APOBEC3G, AL031846.1, APOBEC3H, CBX7, COX5BP7, AL031846.2, FUNDC2P4, PDGFB, AL031590.1.
- chr22:40,857,077–42,090,884, 61 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,835. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
